Gene-level copy-number profile of tumor specimen TCGA-50-6597-01A from TCGA case TCGA-50-6597, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 79.9 years (29,195 days).
Specimen TCGA-50-6597-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUAD.768f2554-8fad-45ab-8d38-52a1b6a60226.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-50-6597-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/b0f9d70f-1942-46a7-8d48-2cda94aff812

Most common (modal) total copy number across autosomal genes: 1 — below the diploid value of 2.
Genes by total copy number (all chromosomes): copy number 1: 28,939; copy number 2: 25,908; copy number 3: 2,944; copy number 4: 997; copy number 5: 248; copy number 6: 188; copy number 7: 223; copy number 8: 1; copy number 9: 174; copy number 10: 81; copy number 11: 26; copy number 15: 26; copy number 17: 1; copy number 20: 5; copy number 21: 6; copy number 26: 47.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, sample TCGA-50-6597-01): tumor purity 0.48, ploidy 3.59, whole-genome doublings 1 (call status: maf_call).

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 3, i.e. more than twice the modal value of 1; autosomes only): 4,674 genes in 34 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:58,198–4,147,429, 95 genes, copy number 3–10 (broad region; genes not listed).
- chr5:8,685,581–32,888,145, 319 genes, copy number 3–10 (broad region; genes not listed).
- chr7:14,145,049–14,974,777, 1 gene, copy number 6 (within-gene range 2–6): DGKB.
- chr7:14,814,131–15,068,651, 3 genes, copy number 6: AC006150.1, GTF3AP5, AC006458.1.
- chr7:19,353,531–20,415,754, 15 genes, copy number 11–17: AC007091.1, POLR1F, MIR3146, TMEM196, AC004543.1, AC005062.1, RPL21P75, AC007001.1, MACC1, MACC1-AS1, AC005083.1, AC099342.1, AC004130.2, ITGB8, AC004130.1.
- chr7:22,419,444–22,882,390, 14 genes, copy number 5 (within-gene range 2–5): STEAP1B, EEF1A1P6, AC002480.1, AC002480.2, IL6-AS1, IL6, MTCYBP42, AC073072.1, TOMM7, AC005682.2, SNHG26, SNORD93, AC005682.1, RPL12P10.
- chr7:24,132,705–24,132,837, 1 gene, copy number 8: RNA5SP228.
- chr8:58,805,412–59,119,147, 1 gene, copy number 5 (within-gene range 1–5): TOX.
- chr8:58,991,720–62,249,879, 42 genes, copy number 5 (within-gene range 1–5): AC105150.1, AC090152.1, AC087698.1, RNA5SP267, AC087664.3, AC087664.1, AC087664.2, AC107934.1, AC107934.2, AC022709.1, AC021393.1, SLC2A13P1, CA8, LINC01301, PDCL3P1, RAB2A, AC068389.3, AC068389.1, AC068389.2, CHD7, AC113143.1, AC113143.2, IFITM3P8, AC022182.1, NASPP1, AC022182.2, CLVS1, NPM1P6, AC023866.2, AC023866.1, ASPH, KRT8P3, RN7SKP97, MIR4470, AC091173.1, LINC02842, AC025524.1, LINC02155, C1GALT1P3, NARS1P2, AC104852.1, AC023095.1.
- chr8:94,553,668–95,811,254, 33 genes, copy number 3 (within-gene range 2–3): AC023632.2, AC023632.1, AC023632.3, AC023632.4, AC108860.2, ESRP1, Metazoa_SRP, AC108860.1, AP005660.1, Y_RNA, DPY19L4, AP003692.1, INTS8, CCNE2, AC087752.4, AC087752.1, NDUFAF6, TP53INP1, AC087752.3, AC087752.2, AC068189.2, RNU6-1209P, MIR3150BHG, AC068189.1, MIR3150B, MIR3150A, PLEKHF2, C8orf37-AS1, LINC01298, C8orf37, AC024995.1, AC083836.1, RNU6-690P.
- chr8:111,225,585–126,008,930, 166 genes, copy number 3–6 (within-gene range 2–6) (broad region; genes not listed).
- chr8:125,900,951–125,901,054, 1 gene, copy number 3: RNU6-442P.
- chr8:128,049,152–128,564,679, 5 genes, copy number 3: MIR1207, MIR1208, RN7SKP226, AC100822.1, LINC00824.
- chr9:14,475–969,090, 20 genes, copy number 3 (within-gene range 2–3): WASHC1, AL449043.2, PGM5P3-AS1, AL449043.1, LINC01388, FOXD4, CBWD1, AL158832.2, DOCK8-AS1, DOCK8, AL158832.1, AL161725.1, KANK1, RPL12P25, AL161725.2, AL392089.1, RNU6-1327P, EIF1P1, AL136979.1, DMRT1.
- chr9:29,214,322–29,636,853, 4 genes, copy number 3: AL162388.2, AL162388.1, AL353684.1, AL354676.1.
- chr9:87,497,228–91,950,228, 84 genes, copy number 3–4 (within-gene range 1–4) (broad region; genes not listed).
- chr9:93,951,627–99,070,792, 138 genes, copy number 3 (broad region; genes not listed).
- chr9:102,256,604–119,524,125, 241 genes, copy number 3–6 (broad region; genes not listed).
- chr9:124,257,606–130,237,303, 194 genes, copy number 3–4 (within-gene range 1–4) (broad region; genes not listed).
- chr12:55,901,413–69,959,097, 358 genes, copy number 4–26 (within-gene range 2–26) (broad region; genes not listed).
- chr12:69,946,543–69,947,081, 1 gene, copy number 26: AC078922.1.
- chr12:70,239,114–72,186,618, 32 genes, copy number 3–7: AC092881.2, CNOT2, AC092881.1, KCNMB4, RNU4-65P, AC025569.1, PTPRB, AC083809.1, PTPRR, FAHD2P1, Y_RNA, AC123905.1, AC025575.1, AC025575.2, TSPAN8, LGR5, AC090116.1, AC078860.3, AC078860.2, ZFC3H1, AC078860.1, THAP2, AC073612.1, TMEM19, AC011601.1, RAB21, AC089984.1, AC089984.2, TBC1D15, MRS2P2, TPH2, AC090109.1.
- chr12:72,249,964–72,276,954, 1 gene, copy number 3 (within-gene range 2–3): TRHDE-AS1.
- chr17:42,647,834–83,095,122, 1,364 genes, copy number 3 (broad region; genes not listed).
- chr19:14,732,392–14,904,138, 11 genes, copy number 3 (within-gene range 1–3): ADGRE2, OR7C1, AC005255.1, OR7A5, OR7A10, OR7A8P, OR7A2P, OR7A17, OR7A18P, OR7A1P, OR7A3P.
- chr19:15,380,050–16,324,514, 56 genes, copy number 3 (within-gene range 2–3): AKAP8L, AC006128.1, WIZ, MIR1470, RASAL3, PGLYRP2, CYP4F22, AC011492.1, CYP4F23P, AD000091.1, RPL23AP2, AC093072.1, CYP4F8, CYP4F3, CYP4F10P, CYP4F12, OR10H2, OR10H3, CYP4F24P, AC004597.1, OR10H5, OR10H1, ZNF861P, AC004510.2, LINC01764, UCA1, AC004510.1, CLEC4O, CYP4F36P, CYP4F2, AC005336.2, AC005336.3, AC005336.1, CYP4F11, OR10H4, CYP4F9P, LINC00661, AC004790.2, LINC00905, SNX33P1, AC004790.1, OR1AB1P, LINC01855, TPM4, AC008894.3, AC008894.1, RAB8A, AC008894.2, HSH2D, CIB3, FAM32A, AC020911.1, Metazoa_SRP, AC020911.3, AP1M1, AC020911.2.
- chr19:19,211,958–40,056,231, 694 genes, copy number 3–9 (within-gene range 1–9) (broad region; genes not listed).
- chr19:43,192,702–44,890,876, 91 genes, copy number 4 (broad region; genes not listed).
- chr19:52,749,942–57,717,301, 384 genes, copy number 3–4 (within-gene range 1–4) (broad region; genes not listed).
- chr19:57,697,367–57,709,194, 1 gene, copy number 4 (within-gene range 1–4): ZNF154.
- chr20:62,872,250–64,313,132, 89 genes, copy number 3 (broad region; genes not listed).
- chr21:22,008,756–27,143,949, 71 genes, copy number 4–5 (within-gene range 2–5) (broad region; genes not listed).
- chr21:34,787,801–36,004,667, 1 gene, copy number 3 (within-gene range 2–3): RUNX1.
- chr21:35,472,095–41,879,482, 143 genes, copy number 3 (within-gene range 2–3) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 27,131. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
